Somatic mutation profile of tumor specimen 0DK842 from CCDI case PBBVRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 23.2 years (8,480 days).
Specimen 0DK842: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 668b3fbb-e7bf-4888-a143-c0ff2df32121.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DK83R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2cabba3c-bb74-4b2a-9807-c48c15237dd7

The open-access MAF lists 64 somatic variants for this specimen: 33 protein-altering or splice-affecting, 14 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 14, Intron 9, 3'UTR 4, Nonsense Mutation 3, Splice Region 2, 5'UTR 2, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADNP | c.2188C>T p.R730* | Nonsense Mutation (SNP) | VAF 276/381 reads (72%) | catalogued as rs886041116, CM166963, COSV100823721; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CABLES2 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 159/656 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as rs756336623; called by muse, mutect2, varscan2
- CHRD | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 38/296 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs746170996; called by muse, mutect2, varscan2
- COPG2 | c.1421G>A p.R474H | Missense Mutation (SNP) | VAF 100/492 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1391581744; called by muse, mutect2, varscan2
- DLX5 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 73/286 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs762671104, COSV56032464; called by muse, mutect2, varscan2
- FLOT2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 92/717 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.505); catalogued as rs767292901; called by muse, mutect2, varscan2
- HCFC1 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 191/323 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV60071422; called by muse, mutect2, varscan2
- INMT | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 100/796 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs781666984; called by muse, mutect2, varscan2
- INSRR | c.2548G>A p.E850K | Missense Mutation (SNP) | VAF 112/544 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63871330; called by muse, mutect2, varscan2
- KAT6A | c.825G>A p.A275= | Splice Region (SNP) | VAF 351/657 reads (53%) | catalogued as rs762682306; called by muse, mutect2, varscan2
- MAP6 | c.1081C>A p.R361S | Missense Mutation (SNP) | VAF 89/364 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59078353; called by muse, mutect2, varscan2
- MYH1 | c.1368G>C p.R456S | Missense Mutation (SNP) | VAF 108/530 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV56856428; called by muse, mutect2, varscan2
- NDRG2 | c.718C>T p.R240C (on ENST00000298687 / NM_001354570.1; = p.R226C on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs777809812, COSV100068959; called by muse, mutect2, varscan2
- RABGGTA | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 66/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1356286059, COSV53771063; called by muse, mutect2, varscan2
- SLC34A2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 106/987 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65941730; called by muse, mutect2, varscan2
- SLC45A4 | c.763G>A p.E255K (on ENST00000517878 / NM_001286646.2; = p.E204K on NM_001080431.2) | Missense Mutation (SNP) | VAF 59/494 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1020706609, COSV50202472; called by muse, mutect2, varscan2
- SLF1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 159/559 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs933822338; called by muse, mutect2, varscan2
- SMARCA4 | c.2644G>A p.E882K | Missense Mutation (SNP) | VAF 240/722 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.881); catalogued as COSV60786460; called by muse, mutect2, varscan2
- SPAG17 | c.4490G>A p.R1497H | Missense Mutation (SNP) | VAF 191/519 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs370369450; called by muse, mutect2, varscan2
- STYK1 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 81/436 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.951); catalogued as rs1172518849, COSV50015322; called by muse, mutect2, varscan2
- SVEP1 | c.6787G>A p.D2263N | Missense Mutation (SNP) | VAF 42/554 reads (8%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs370877731; called by muse, mutect2
- WDR76 | c.46C>T p.R16* | Nonsense Mutation (SNP) | VAF 51/175 reads (29%) | catalogued as rs1364572508; called by muse, mutect2, varscan2
- ZNF497 | c.1045C>T p.R349W | Missense Mutation (SNP) | VAF 59/416 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs552275342; called by muse, mutect2, varscan2
- ZNF662 | c.1037A>G p.D346G | Missense Mutation (SNP) | VAF 97/624 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs751140995; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 40/964 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- COL6A2 | c.2034C>G p.D678E | Missense Mutation (SNP) | VAF 108/1333 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KNOP1 | c.107A>G p.D36G | Missense Mutation (SNP) | VAF 61/359 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- PRKDC | c.7915C>T p.Q2639* | Nonsense Mutation (SNP) | VAF 102/932 reads (11%) | called by muse, mutect2, varscan2
- PRPF4B | c.1961T>C p.I654T | Missense Mutation (SNP) | VAF 130/442 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SCN11A | c.2461G>A p.G821R | Missense Mutation (SNP) | VAF 38/1166 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); called by muse, mutect2
- SORBS3 | c.817-3dup | Splice Region (INS) | VAF 36/280 reads (13%) | called by mutect2, varscan2
- TAGAP | c.59C>T p.T20I | Missense Mutation (SNP) | VAF 101/747 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- TMTC2 | c.596A>G p.Y199C | Missense Mutation (SNP) | VAF 114/637 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACOT11 | c.1323G>T p.L441= | Silent (SNP) | VAF 101/632 reads (16%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.3756C>T p.S1252= | Silent (SNP) | VAF 105/578 reads (18%) | catalogued as rs376681507; called by muse, mutect2, varscan2
- EVC | c.1374A>T p.G458= | Silent (SNP) | VAF 118/877 reads (13%) | called by muse, mutect2, varscan2
- GALR3 | c.516C>T p.C172= | Silent (SNP) | VAF 34/225 reads (15%) | called by muse, mutect2, varscan2
- IQGAP2 | c.2880T>C p.G960= | Silent (SNP) | VAF 55/561 reads (10%) | called by muse, mutect2
- LGALS7B | c.216C>T p.R72= | Silent (SNP) | VAF 74/1338 reads (6%) | catalogued as rs1243301065; called by muse, mutect2
- LRP2 | c.8946C>T p.Y2982= | Silent (SNP) | VAF 212/449 reads (47%) | catalogued as rs781541482, COSV55547693; called by muse, mutect2, varscan2
- PSMC4 | c.552G>A p.P184= | Silent (SNP) | VAF 101/474 reads (21%) | catalogued as rs755531098, COSV50096297; called by muse, mutect2, varscan2
- PXDN | c.2904C>T p.I968= | Silent (SNP) | VAF 33/225 reads (15%) | catalogued as rs781271519, COSV99414548; called by muse, mutect2, varscan2
- SEMA5A | c.2793C>T p.S931= | Silent (SNP) | VAF 442/905 reads (49%) | catalogued as rs372731799; called by muse, mutect2, varscan2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 24/702 reads (3%) | called by muse, mutect2
- TDRD15 | c.288C>T p.R96= | Silent (SNP) | VAF 86/315 reads (27%) | catalogued as rs764197433; called by muse, mutect2, varscan2
- UGT2B15 | c.300T>A p.G100= | Silent (SNP) | VAF 66/612 reads (11%) | catalogued as rs1455314526; called by muse, mutect2, varscan2
- ZNF341 | c.645C>T p.N215= | Silent (SNP) | VAF 331/480 reads (69%) | catalogued as rs773307366, COSV61011310; called by muse, mutect2, varscan2
- ASL | c.719-85dup | Intron (INS) | VAF 70/157 reads (45%) | called by mutect2, varscan2
- C8orf86 | n.315C>T | RNA (SNP) | VAF 17/156 reads (11%) | called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 16/166 reads (10%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 18/164 reads (11%) | called by muse, varscan2
- COMMD4 | c.*41G>A | 3'UTR (SNP) | VAF 203/328 reads (62%) | catalogued as rs147946131; called by muse, mutect2, varscan2
- CT47B1 | c.-12G>A | 5'UTR (SNP) | VAF 48/220 reads (22%) | catalogued as rs755377925; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8611G>A | Intron (SNP) | VAF 82/622 reads (13%) | catalogued as rs1277201203; called by muse, varscan2
- ERLIN1 | c.*48del | 3'UTR (DEL) | VAF 52/102 reads (51%) | called by mutect2, varscan2
- KHNYN | c.*4383del | 3'UTR (DEL) | VAF 76/180 reads (42%) | catalogued as rs1490280065; called by mutect2, varscan2
- KLHL38 | c.*40T>G | 3'UTR (SNP) | VAF 19/326 reads (6%) | called by muse, mutect2
- KLK5 | c.592+42G>A | Intron (SNP) | VAF 144/261 reads (55%) | catalogued as rs368001515; called by muse, mutect2, varscan2
- MAFA | c.-58G>C | 5'UTR (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- PCID2 | c.37-95A>C | Intron (SNP) | VAF 3/32 reads (9%) | catalogued as COSV55814242; called by muse, mutect2
- PRSS2 | c.200+322T>C | Intron (SNP) | VAF 19/363 reads (5%) | catalogued as rs1372302238; called by muse, mutect2
- RO60 | chr1:193091578 A>G | 3'Flank (SNP) | VAF 24/108 reads (22%) | called by muse, mutect2, varscan2
- SLC9A1 | c.1485+34G>T | Intron (SNP) | VAF 85/454 reads (19%) | called by muse, mutect2, varscan2
- TRUB2 | c.378+90G>A | Intron (SNP) | VAF 18/99 reads (18%) | called by muse, mutect2, varscan2
